Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A5XM, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A5XM-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Adrenal gland, left, robotic laparoscopic adrenalectomy

Histologic tumor type: Pheochromocytoma

Tumor size (greatest dimension): 3.4 cm, gross measurement

Tumor gland weight: Estimated 18 g (estimated, see comment)

Specimen integrity: Disrupted

Specimen size: 119 g, 13 x 7 x 4 cm

Specimen laterality: Left

Invasive properties:

Capsule: Not identified

Extra-adrenal tissues: Not identified

Lymphovascular: Not identified

Blood vascular: Not identified

Histologic assessment of surgical margins: Not involved by tumor

Status of adrenal gland away from tumor: Unremarkable

Lymph nodes:

Number of lymph nodes involved: N/A

Number of lymph nodes examined: 0

Comment:

Immunohistochemical staining for Ki-67 revealed a labelling index of <1%.

Tumor gland mass is estimated. Precise measurement was not possible without disrupting margins. Estimated tumor mass is approximately 7 g.

ECD-0-3

Pheochromocytoma NOS 8700/0

Site: (L) Adrenal Gland NOS
074.9

JW 4/3/13

[page 2 of 3]
Clinical History:

year-old male with an adrenal mass. Per he has a 3.5 cm mass in the left adrenal gland. Urine and serum metanephrines are both elevated, consistent with a clinical diagnosis of pheochromocytoma.

Gross Description:

Received is one appropriately labeled container, additionally labeled "adrenals."

Specimen fixation: formalin

Type of specimen: adrenalectomy

Size and weight of specimen: Overall: 119.4 grams, 13 x 7 x 4 cm; Adrenal gland 7.6 x 4.0 x 1.8 cm. The adrenal represents approximately 15% of the entire mass of the specimen.

Structures attached to adrenal gland, if applicable: periadrenal adipose tissue

Orientation: The specimen is received markedly disrupted with the periadrenal adipose tissue absent over a 3.0 x 1.5 cm area. The adrenal gland underlying this region has a 2.6 cm linear disruption which has been sutured closed. The periadrenal adipose tissue and exposed adrenal gland are inked blue on the side of this disruption. The periadrenal adipose tissue is inked black on the non-disrupted side. However, given the disruption, the marginal tissue is poorly adherent to the adrenal gland, compromising assessment of margins.

Tumor description: brown, well circumscribed and grossly necrotic, emerging from and restricted to the medulla

Tumor weight: Tumor, immediately adjacent normal adrenal gland and immediately adjacent periadrenal adipose tissue weighs 14.6 grams (after removal of distant adrenal gland and non-marginal periadrenal adipose tissue. Tumor represents approximately 50% of the mass of this tissue)

Tumor size: 3.4 x 2.0 x 1.6 cm

Confinement/Non-confinement to the adrenal gland: Grossly appears confined, however, disruption of the surgical margins comprises assessment of confinement

[page 3 of 3]
Distance of tumor from surgical margins: 1 mm to the closest black inked periadrenal resection margin (non-disrupted side); less than 1 mm to the closest blue inked periadrenal resection margin (disrupted side)

Appearance of adrenal gland away from tumor: Golden yellow/tan cortex, ranging in thickness from less than 1 mm to 1 mm, with a brown central medulla. No additional masses or hemorrhage.

Lymph nodes: none identified

Tissue submitted for special investigations: Tumor is submitted to Tissue Procurement

Digital photograph taken: not taken

Block summary:

(Inking: black=non-disrupted side, blue=disrupted side)

A1-A10 - mass, entirely submitted; Closest blue inked margin in A3; closest black inked margin in A6

A11-A12 - representative sections of uninvolved adrenal gland

Uninvolved adrenal and periadrenal adipose remains in formalin.

Malignant behavior not defined - no
staging - assume uncertain malignant behavior.

Source: NCI Genomic Data Commons file 09d7dae6-3e6b-44c3-942f-dad2d17aee15 (TCGA-QT-A5XM.43F2E29C-B8D4-41D5-9B3E-B36F1A2CF1D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).